Somatic mutation profile of tumor specimen MMRF_2719_1_BM_CD138pos (aliquot MMRF_2719_1_BM_CD138pos_T1_KHS5U_L14818) from MMRF case MMRF_2719, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 59.0 years (21,558 days).
Specimen MMRF_2719_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 701ce5d6-2de3-49b8-b0ba-8b4c486c1a62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2719_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2719_1_PB_WBC_C2_KHS5U_L14819; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0ed5898-66de-484e-b94f-a6d45e665197

The open-access MAF lists 100 somatic variants for this specimen: 33 protein-altering or splice-affecting, 18 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, 3'UTR 23, Silent 18, Intron 10, RNA 7, 5'Flank 5, 5'UTR 4, Nonsense Mutation 4, Frame Shift Del 2, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C3orf85 | c.164T>C p.V55A | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs753477030; called by muse, mutect2, varscan2
- CD5L | c.170A>T p.D57V | Missense Mutation (SNP) | VAF 109/224 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs934702931; called by muse, mutect2, varscan2
- GJD4 | c.926A>T p.Q309L | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs1189625218; called by muse, mutect2, varscan2
- H1-4 | c.491C>T p.A164V | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.677); catalogued as rs576653028, COSV56800056, COSV56800948; called by muse, mutect2, varscan2
- ITGB6 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780376574, COSV51791152, COSV51796755; called by muse, mutect2, varscan2
- KLK6 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 56/138 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as rs372505913; called by muse, mutect2, varscan2
- KRT23 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.105); catalogued as rs148371500, COSV52928710; called by muse, mutect2, varscan2
- MASTL | c.61G>T p.V21L | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs778156826; called by muse, mutect2, varscan2
- MID2 | c.703C>T p.R235* | Nonsense Mutation (SNP) | VAF 34/47 reads (72%) | catalogued as COSV53307513; called by muse, mutect2, varscan2
- OR6B1 | c.421T>C p.C141R | Missense Mutation (SNP) | VAF 94/197 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68770436; called by muse, mutect2, varscan2
- RTN1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 77/220 reads (35%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs370975029; called by muse, mutect2, varscan2
- TACC2 | c.6184C>T p.Q2062* (on ENST00000334433; = p.Q140* on NM_006997.4) | Nonsense Mutation (SNP) | VAF 81/470 reads (17%) | catalogued as COSV99586702; called by muse, mutect2, varscan2
- TTC29 | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.18); catalogued as rs910127490; called by muse, mutect2, varscan2
- ZNF860 | c.581G>T p.R194I | Missense Mutation (SNP) | VAF 71/200 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as rs1281718244, COSV100824444, COSV64383847; called by muse, mutect2, varscan2
- ARHGEF33 | c.1221G>A p.Q407= | Splice Region (SNP) | VAF 50/140 reads (36%) | called by muse, mutect2, varscan2
- ARNT | c.137+2T>C p.X46_splice | Splice Site (SNP) | VAF 120/309 reads (39%) | called by muse, mutect2, varscan2
- CBLL2 | c.1179G>A p.W393* | Nonsense Mutation (SNP) | VAF 69/85 reads (81%) | called by muse, mutect2, varscan2
- DNAH5 | c.13087A>C p.M4363L | Missense Mutation (SNP) | VAF 31/60 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- GANC | c.972G>A p.W324* | Nonsense Mutation (SNP) | VAF 53/325 reads (16%) | called by muse, mutect2, varscan2
- IGKV2-28 | c.132G>C p.R44S | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, varscan2
- IGLV3-1 | c.183_210del p.P62Sfs*21 | Frame Shift Del (DEL) | VAF 64/110 reads (58%) | called by mutect2, pindel, varscan2
- MAP4K4 | c.946A>G p.K316E | Missense Mutation (SNP) | VAF 29/123 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- MPZL1 | c.397T>C p.Y133H | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PCMT1 | c.593-4_593dup | Splice Region (INS) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- PIKFYVE | c.4603G>A p.E1535K | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRKD2 | c.1148G>C p.R383T | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SRSF7 | c.538_539del p.R180Vfs*55 | Frame Shift Del (DEL) | VAF 45/151 reads (30%) | called by mutect2, pindel, varscan2
- STAM | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TENM3 | c.1873T>G p.C625G | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WDFY3 | c.4160T>C p.L1387P | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- WDFY3 | c.2649A>T p.Q883H | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ZNF26 | c.667G>T p.V223F | Missense Mutation (SNP) | VAF 97/236 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- ZNF648 | c.814C>A p.R272S | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- ANO4 | c.630G>A p.R210= (on ENST00000392977 / NM_001286615.2; = p.R175= on NM_178826.4) | Silent (SNP) | VAF 53/147 reads (36%) | called by muse, mutect2, varscan2
- CEP295 | c.5175G>A p.Q1725= | Silent (SNP) | VAF 111/285 reads (39%) | called by muse, mutect2, varscan2
- DIAPH2 | c.2607A>T p.S869= | Silent (SNP) | VAF 23/27 reads (85%) | called by muse, mutect2
- EIF2B1 | c.342G>A p.L114= | Silent (SNP) | VAF 106/302 reads (35%) | called by muse, mutect2, varscan2
- GABRA1 | c.843A>T p.A281= | Silent (SNP) | VAF 86/208 reads (41%) | called by muse, mutect2, varscan2
- GUCY2C | c.819G>A p.V273= | Silent (SNP) | VAF 85/194 reads (44%) | catalogued as rs779177049; called by muse, mutect2, varscan2
- HAL | c.1650G>A p.E550= | Silent (SNP) | VAF 28/66 reads (42%) | catalogued as rs1390489238; called by muse, mutect2, varscan2
- KRT80 | c.705G>A p.S235= | Silent (SNP) | VAF 42/114 reads (37%) | catalogued as rs764851000; called by muse, mutect2, varscan2
- MPO | c.1387C>T p.L463= | Silent (SNP) | VAF 95/232 reads (41%) | catalogued as COSV56567550; called by muse, mutect2, varscan2
- NRXN1 | c.738G>T p.S246= | Silent (SNP) | VAF 22/73 reads (30%) | catalogued as COSV68014853; called by muse, mutect2, varscan2
- OR14C36 | c.579T>C p.N193= | Silent (SNP) | VAF 59/151 reads (39%) | called by muse, mutect2, varscan2
- PAK5 | c.360G>A p.A120= | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs764811122, COSV62033998; called by muse, mutect2, varscan2
- PCDH10 | c.2394C>T p.N798= | Silent (SNP) | VAF 85/191 reads (45%) | called by muse, mutect2, varscan2
- PCNX2 | c.2121T>C p.D707= | Silent (SNP) | VAF 34/338 reads (10%) | catalogued as rs1558393097; called by muse, mutect2, varscan2
- TSPAN18 | c.462A>G p.E154= | Silent (SNP) | VAF 136/335 reads (41%) | catalogued as rs765481103; called by muse, mutect2, varscan2
- TSPO2 | c.216G>A p.L72= | Silent (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- ZCWPW1 | c.1060C>T p.L354= | Silent (SNP) | VAF 31/73 reads (42%) | catalogued as rs937551114, COSV61248784; called by muse, mutect2, varscan2
- ZNF780B | c.339C>T p.L113= | Silent (SNP) | VAF 82/216 reads (38%) | catalogued as rs766830919, COSV55463726; called by muse, mutect2, varscan2
- AC016705.2 | n.112T>G | RNA (SNP) | VAF 67/114 reads (59%) | called by muse, mutect2, varscan2
- ACAP3 | c.916-96G>C | Intron (SNP) | VAF 11/19 reads (58%) | called by muse, mutect2, varscan2
- ADARB2 | c.-126A>G | 5'UTR (SNP) | VAF 37/118 reads (31%) | called by muse, mutect2, varscan2
- AGGF1 | c.*941del | 3'UTR (DEL) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- BORCS8 | c.*17G>A | 3'UTR (SNP) | VAF 11/26 reads (42%) | called by muse, mutect2, varscan2
- C5orf24 | c.*3488G>A | 3'UTR (SNP) | VAF 21/50 reads (42%) | called by muse, mutect2, varscan2
- CARMIL3 | chr14:24048808 G>A | 5'Flank (SNP) | VAF 72/209 reads (34%) | called by muse, mutect2, varscan2
- CAST | chr5:96662058 C>T | 5'Flank (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- CRHBP | c.*168del | 3'UTR (DEL) | VAF 26/90 reads (29%) | called by mutect2, varscan2
- CRHBP | c.*169T>C | 3'UTR (SNP) | VAF 27/87 reads (31%) | called by mutect2, varscan2
- CYP2C9 | c.*52C>T | 3'UTR (SNP) | VAF 43/94 reads (46%) | catalogued as rs767891172; called by muse, mutect2, varscan2
- DESI2 | c.-149C>G | 5'UTR (SNP) | VAF 11/36 reads (31%) | called by muse, mutect2, varscan2
- DLGAP2 | c.*4139G>A | 3'UTR (SNP) | VAF 88/186 reads (47%) | called by muse, mutect2
- ERCC2 | chr19:45370719 G>A | 5'Flank (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- EXOC6 | c.*1085T>G | 3'UTR (SNP) | VAF 23/78 reads (29%) | catalogued as rs1485066156; called by muse, mutect2, varscan2
- FGFR3 | c.*1467_*1489delinsGG | 3'UTR (DEL) | VAF 40/110 reads (36%) | called by pindel, varscan2*
- FOXI2 | c.*453G>T | 3'UTR (SNP) | VAF 43/99 reads (43%) | called by muse, mutect2, varscan2
- FOXP1 | c.*3381G>T | 3'UTR (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- GLCCI1 | c.696+28A>T | Intron (SNP) | VAF 74/177 reads (42%) | called by muse, mutect2, varscan2
- GNA14 | c.-427C>G | 5'UTR (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- GPM6A | c.*1412C>T | 3'UTR (SNP) | VAF 27/72 reads (38%) | called by muse, mutect2, varscan2
- HILPDA | chr7:128455853 G>A | 5'Flank (SNP) | VAF 31/72 reads (43%) | catalogued as rs1249735538; called by mutect2, varscan2
- IGKV2-29 | n.119T>C | RNA (SNP) | VAF 88/211 reads (42%) | catalogued as rs772196009; called by muse, varscan2
- IL17RD | c.*6237G>A | 3'UTR (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- IQCA1 | c.1956+796C>T | Intron (SNP) | VAF 47/134 reads (35%) | called by muse, mutect2, varscan2
- IQGAP2 | c.908-92T>G | Intron (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2
- LINC00602 | n.1310G>A | RNA (SNP) | VAF 38/52 reads (73%) | called by muse, mutect2, varscan2
- MAGOH3P | n.305C>T | RNA (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851308 C>T | 5'Flank (SNP) | VAF 77/191 reads (40%) | catalogued as rs746618485; called by muse, mutect2, varscan2
- NCL | c.1705+145A>C | Intron (SNP) | VAF 36/109 reads (33%) | called by muse, mutect2
- OSBPL10 | c.*542T>A | 3'UTR (SNP) | VAF 34/84 reads (40%) | called by muse, mutect2, varscan2
- PAX5 | c.-56G>A | 5'UTR (SNP) | VAF 6/25 reads (24%) | catalogued as rs1034943970; called by muse, mutect2, varscan2
- PCDH15 | c.*231A>C | 3'UTR (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- PRTG | c.397+2134T>A | Intron (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- PTGS2 | c.*1622T>G | 3'UTR (SNP) | VAF 53/226 reads (23%) | called by muse, mutect2, varscan2
- RBM4 | c.-12-292T>C | Intron (SNP) | VAF 83/221 reads (38%) | called by muse, mutect2, varscan2
- SLC12A1 | c.1215+104C>T | Intron (SNP) | VAF 160/265 reads (60%) | called by muse, mutect2, varscan2
- SLC1A3 | c.181+4353G>A | Intron (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2
- SLC25A12 | c.*44A>T | 3'UTR (SNP) | VAF 79/187 reads (42%) | called by muse, mutect2, varscan2
- SLC7A4 | c.*67G>A | 3'UTR (SNP) | VAF 32/155 reads (21%) | catalogued as rs1428070035; called by muse, varscan2
- SLC7A4 | c.*12A>G | 3'UTR (SNP) | VAF 16/86 reads (19%) | called by muse, varscan2
- SPATA8 | n.1398C>T | RNA (SNP) | VAF 32/103 reads (31%) | catalogued as rs918201539; called by muse, mutect2, varscan2
- STIM1 | c.*732dup | 3'UTR (INS) | VAF 54/143 reads (38%) | called by mutect2, pindel, varscan2
- STX6 | c.490-15T>A | Intron (SNP) | VAF 42/113 reads (37%) | called by muse, mutect2, varscan2
- TNFAIP1 | c.*1649G>C | 3'UTR (SNP) | VAF 44/84 reads (52%) | called by muse, mutect2, varscan2
- TTC3P1 | n.5529C>T | RNA (SNP) | VAF 54/67 reads (81%) | catalogued as rs749373553; called by muse, mutect2, varscan2
- TXNL1 | c.*4457G>A | 3'UTR (SNP) | VAF 32/79 reads (41%) | catalogued as rs1326794842; called by muse, mutect2, varscan2
- VAMP4 | c.*3096T>C | 3'UTR (SNP) | VAF 59/119 reads (50%) | called by muse, mutect2, varscan2
- VWFP1 | n.1625C>A | RNA (SNP) | VAF 77/208 reads (37%) | called by muse, mutect2, varscan2
